Gene-level copy-number profile of tumor specimen ALCH-B1MW-TTP1-A from ALCHEMIST case ALCH-B1MW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 63.5 years (23,197 days).
Specimen ALCH-B1MW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2863fb73-68e0-4c2b-bc7f-ff7807052cae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1MW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/5d1353de-3ffe-4d9e-a0d8-baa124241471

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 3,521; copy number 2: 54,368; copy number 3: 514; copy number 4: 91; copy number 5: 96; copy number 6: 2; copy number 7: 22; copy number 8: 60; copy number 9: 53; copy number 10: 73; copy number 12: 1; copy number 16: 11.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,454,665–3,611,508, 4 genes: ARHGEF16, AL512413.1, MEGF6, MIR551A.
- chr1:16,855,407–16,859,284, 2 genes (within-gene range 0–2): BX284668.3, MIR3675.
- chr2:239,068,817–239,085,926, 2 genes (within-gene range 0–2): MIR4440, MIR4441.
- chr3:50,558,025–50,596,168, 2 genes: C3orf18, HEMK1.
- chr4:2,793,071–2,841,098, 1 gene: SH3BP2.
- chr5:1,510,762–1,510,856, 1 gene (within-gene range 0–2): MIR6075.
- chr6:36,940,071–36,944,675, 1 gene: AL122034.1.
- chr7:157,868,538–157,869,154, 1 gene (within-gene range 0–2): AC011899.2.
- chr8:144,495,458–144,507,174, 2 genes (within-gene range 0–2): AC084125.2, GPT.
- chr12:130,138,693–130,140,768, 1 gene: AC026336.3.
- chr12:130,144,954–130,145,691, 1 gene (within-gene range 0–2): AC026336.5.
- chr15:77,894,684–77,904,674, 1 gene: CSPG4P13.
- chr16:85,814,425–85,816,536, 2 genes: AC018695.5, AC018695.1.
- chr17:7,380,534–7,444,081, 12 genes (within-gene range 0–2): TNK1, PLSCR3, TMEM256-PLSCR3, TMEM256, NLGN2, AC113189.2, SPEM1, SPEM2, SPEM3, AC113189.12, TMEM102, AC113189.1.
- chr17:50,133,737–50,150,677, 2 genes: PPP1R9B, AC002401.1.
- chr19:7,898,804–7,923,250, 6 genes (within-gene range 0–2): AC010336.1, MAP2K7, AC010336.4, TGFBR3L, AC010336.2, SNAPC2.
- chr19:7,926,718–7,943,667, 1 gene (within-gene range 0–3): TIMM44.
- chr21:44,133,610–44,210,114, 1 gene (within-gene range 0–4): GATD3A.
- chr22:50,445,000–50,475,035, 1 gene (within-gene range 0–1): SBF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 316 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,164,008–183,163,839, 92 genes, copy number 5 (broad region; genes not listed).
- chr7:157,501,322–157,503,908, 1 gene, copy number 9: AC006372.1.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.
- chr16:981,770–1,000,926, 2 genes, copy number 5: SOX8, AC009041.1.
- chr17:18,426,861–18,442,895, 2 genes, copy number 10: KRT17P2, KRT16P1.
- chr21:44,107,373–44,131,181, 1 gene, copy number 6: PWP2.
- chr22:15,282,557–15,529,139, 7 genes, copy number 8: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1.
- chr22:16,428,947–17,329,232, 52 genes, copy number 9: SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.3, ZNF402P, AC007064.2, MTND1P17, AC007064.1, AC006548.1, IGKV1OR22-5, IGKV2OR22-4, IGKV2OR22-3, IGKV3OR22-2, IGKV1OR22-1, AC006548.3, GAB4, AC006548.2, VN1R9P, CECR7, AC006946.2, AC006946.3, IL17RA, AC006946.1, TMEM121B, LINC01664, HDHD5, HDHD5-AS1, ADA2, AC005300.1, FAM32BP, CECR3, CECR9.
- chr22:18,715,815–18,719,341, 1 gene, copy number 12: PPP1R26P4.
- chr22:18,873,543–21,551,461, 157 genes, copy number 7–16 (within-gene range 2–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
